Somatic mutation profile of tumor specimen TCGA-E1-A7YQ-01A (aliquot TCGA-E1-A7YQ-01A-11D-A34J-08) from TCGA case TCGA-E1-A7YQ, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Oligodendroglioma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 58.4 years (21,341 days).
Specimen TCGA-E1-A7YQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4b2c92e3-e4a9-4ad6-892c-8a10c60d11ea.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-E1-A7YQ-10A (Blood Derived Normal), aliquot TCGA-E1-A7YQ-10A-01D-A34M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c4e20e5a-fdcd-419f-a8fb-fcd8a2930467

The open-access MAF lists 31 somatic variants for this specimen: 27 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 23, Silent 4, Frame Shift Del 2, In Frame Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKAP13 | c.7693C>A p.P2565T (on ENST00000394518 / NM_007200.5; = p.P2569T on NM_006738.6) | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV100773082; called by muse, mutect2, varscan2
- BUB1 | c.1531T>A p.S511T | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.499); catalogued as COSV100240821; called by muse, mutect2, varscan2
- CACNB3 | c.637T>C p.S213P | Missense Mutation (SNP) | VAF 16/123 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.678); catalogued as COSV99974650; called by muse, mutect2, varscan2
- CLSTN3 | c.1675G>A p.E559K | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.15); catalogued as COSV56938535; called by muse, mutect2, varscan2
- DCAF12L2 | c.661C>T p.R221W | Missense Mutation (SNP) | VAF 6/93 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as COSV100758442, COSV63583588; called by muse, mutect2
- DCAF8L1 | c.1289G>C p.R430T | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.045); catalogued as COSV101491378, COSV101491574; called by muse, mutect2, varscan2
- DIS3 | c.1649C>T p.S550F | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66708362; called by muse, mutect2, varscan2
- EGF | c.3560C>A p.S1187* | Nonsense Mutation (SNP) | VAF 16/160 reads (10%) | catalogued as COSV54479745, COSV99490449; called by muse, mutect2
- EGFR | c.1994G>A p.G665D | Missense Mutation (SNP) | VAF 415/504 reads (82%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.726); catalogued as COSV99286607; called by muse, mutect2, varscan2
- FAM47B | c.728G>A p.R243H | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.023); catalogued as rs767477342, COSV61452830, COSV61454653; called by muse, mutect2, varscan2
- HEG1 | c.428T>C p.M143T | Missense Mutation (SNP) | VAF 29/57 reads (51%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as COSV100230009; called by muse, mutect2, varscan2
- HHIPL1 | c.1022G>T p.G341V | Missense Mutation (SNP) | VAF 77/262 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100414955; called by muse, mutect2, varscan2
- IGKV5-2 | c.307G>A p.A103T | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs549578138; called by muse, mutect2, varscan2
- KCNA5 | c.685C>T p.R229C | Missense Mutation (SNP) | VAF 16/115 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.018); catalogued as rs1555100213, COSV99363588; called by muse, mutect2, varscan2
- MUC17 | c.10801G>C p.V3601L | Missense Mutation (SNP) | VAF 22/183 reads (12%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.959); catalogued as COSV100071526; called by muse, mutect2, varscan2
- MYO15A | c.1048G>A p.D350N | Missense Mutation (SNP) | VAF 16/156 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.038); catalogued as rs1222605746, COSV52756863; called by muse, mutect2, varscan2
- SOWAHB | c.1186G>C p.D396H | Missense Mutation (SNP) | VAF 37/112 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV100530576, COSV57554584; called by muse, mutect2, varscan2
- TACC2 | c.8666A>G p.N2889S (on ENST00000334433; = p.N967S on NM_006997.4) | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs746827175, COSV53283789, COSV99586554; called by muse, mutect2, varscan2
- TLR7 | c.1427G>C p.R476T | Missense Mutation (SNP) | VAF 41/151 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.084); catalogued as COSV101027705; called by muse, mutect2, varscan2
- TMCO3 | c.86C>T p.A29V | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT tolerated (0.24); PolyPhen benign (0.015); catalogued as rs1440508345, COSV100215063; called by muse, mutect2, varscan2
- TVP23B | c.70A>G p.N24D | Missense Mutation (SNP) | VAF 21/101 reads (21%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV100314438; called by muse, mutect2, varscan2
- VTI1A | c.35T>C p.F12S | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV101024320; called by muse, mutect2, varscan2
- ZNF157 | c.202C>A p.L68I | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.08); catalogued as COSV100998430; called by muse, mutect2
- ZSCAN1 | c.265G>A p.A89T | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.687); catalogued as rs148253808; called by muse, mutect2, varscan2
- MTCL1 | c.2203_2213del p.L735Cfs*12 (on ENST00000306329 / NM_001378206.1; = p.L375Cfs*12 on NM_015210.4) | Frame Shift Del (DEL) | VAF 11/53 reads (21%) | called by mutect2, pindel, varscan2
- PBRM1 | c.3582del p.I1195Sfs*23 (on ENST00000296302 / NM_001366071.2; = p.I1170Sfs*23 on NM_018313.5) | Frame Shift Del (DEL) | VAF 31/75 reads (41%) | called by mutect2, pindel, varscan2
- SCCPDH | c.607_654del p.G203_N218del | In Frame Del (DEL) | VAF 28/188 reads (15%) | called by mutect2, pindel
- ARHGEF1 | c.582G>A p.A194= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as rs781919682, COSV100528842; called by muse, varscan2
- CASP4 | c.1128C>A p.G376= | Silent (SNP) | VAF 11/51 reads (22%) | catalogued as rs1382200975, COSV101274108; called by muse, mutect2, varscan2
- MCRS1 | c.210T>C p.S70= | Silent (SNP) | VAF 70/228 reads (31%) | catalogued as COSV100657249; called by muse, mutect2, varscan2
- ZNF557 | c.1020C>G p.P340= (on ENST00000414706 / NM_001044388.2; = p.P347= on NM_024341.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 30/84 reads (36%) | catalogued as COSV99422241; called by muse, mutect2, varscan2
